Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IB, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IB-01A (Primary Tumor).

[page 1 of 5]
Pathology Report

ICD-6-3

Adenocarcinoma, duct
8506/3
Site: Pancreas head
C25.0

QJ 4/16/14

Final Diagnosis

- A. LIVER, RIGHT LOBE, "NODULES", EXCISION:
Hepatic parenchyma with micro and macrovesicular steatosis.
There is cautery artifact.
There is no evidence of malignancy.
- B. LIVER, RIGHT LOBE, "NODULE # 2", EXCISION:
Severely cauterized hepatic parenchyma and focal necrosis.
There is no evidence of viable tumor.
- C. LIVER, LEFT LOBE, "NODULES", EXCISION:
Severely cauterized hepatic parenchyma and focal necrosis.
There is no evidence of malignancy.
- D. LIVER, RIGHT LOBE, "NODULE (TRU-CUT)", EXCISION:
Hepatic parenchyma with micro and macrovesicular steatosis.
There is no evidence of malignancy.
- E. LIVER, RIGHT LOBE, "NODULE (TRU-CUT) # 2", EXCISION:
Hepatic parenchyma with minimal steatosis.
There is no evidence of malignancy.
- F. LYMPH NODE, COMMON HEPATIC, EXCISION:
One lymph node involved by metastatic adenocarcinoma (+1/1).
Extracapsular extension is absent.
- G. LYMPH NODE, POSTERIOR TO REPLACED RIGHT HEPATIC, EXCISION:
One lymph node, negative for malignancy (0/1).
- H. LYMPH NODE, JUNCTION OF UNCINATE PROCESS AND REPLACED RIGHT HEPATIC, EXCISION:
Fragmented lymph node, positive for metastatic adenocarcinoma (+1/1).
Focal extracapsular extension is present.
- I. PORTION OF STOMACH, DUODENUM, GALLBLADDER, AND HEAD OF PANCREAS, PANCREATODUODENECTOMY (WHIPPLE):
Invasive pancreatic ductal adenocarcinoma, poorly differentiated.
Intraductal papillary mucinous neoplasm (IPMN) with low grade dysplasia and focal moderate grade dysplasia involving secondary ducts.
Five of twenty-one lymph nodes involved by metastatic adenocarcinoma (+5/21) with extracapsular extension.
Tumor is less than 1 mm from the vascular groove and 1 mm from the uncinate margin.
-

[page 2 of 5]
Pancreatic margin is involved by IPMN with low grade dysplasia and negative for invasive carcinoma.

Proximal gastric, distal duodenal, common bile duct, and retroperitoneal margins are free of tumor. (See Comment and Key Pathological Findings).

Gallbladder with chronic cholecystitis and no evidence of malignancy.

I, _____, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Key Pathological Findings

I: Pancreas-Exocrine Synoptic Data

SPECIMEN TYPE: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE: Invasive:

4.0 cm

*OTHER ORGANS RESECTED::

*OTHER ORGANS RESECTED: *Gallbladder

*Duodenum

*Distal Stomach

Ductal adenocarcinoma

HISTOLOGIC GRADE: G3: Poorly differentiated

EXTENT OF INVASION - PRIMARY TUMOR: Tumor invades adjacent structures/organs

Duodenum

PRIMARY TUMOR (pT): pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN): pN1b: Metastasis in multiple regional lymph nodes

*Specify Location: Peripancreatic

Number examined: 21

Number involved: 5

DISTANT METASTASIS (pM): pMX: Cannot be assessed

MARGINS:

Margins free of tumor

Tumor is less than 1 mm from the vascular groove margin

PANCREATIC RESECTION MARGIN, INVOLVED BY::

IPMN with low-grade dysplasia

*VENOUS (LARGE VESSEL) INVASION (V): *Absent

*LYMPHATIC (SMALL VESSEL) INVASION (L): *Present

*PERINEURAL INVASION: *Present

*ADDITIONAL PATHOLOGIC FINDINGS:

*Chronic pancreatitis

*Cholecystitis

Intraductal papillary mucinous neoplasm with low grade dysplasia and focal moderate grade dysplasia extending into secondary ducts

Acute serositis of duodenum.

[page 3 of 5]
Specimen(s) Received

A RIGHT LOBE OF LIVER NODULE FS
B RIGHT LOBE OF LIVER NODULE #2 FS
C LEFT LOBE OF LIVER NODULE FS
D LIVER NODULE RIGHT LOBE FS
E LIVER NODULE RIGHT LOBE #2 FS
F COMMON HEPATIC NODE FS
G LYMPH NODE POSTERIOR TO REPLACED RIGHT HEPATIC FS
H JUNCTION OF UNCINATE PROCESS REPLACE RIGHT HEPATIC FS
I WHIPPLE 2 FS

Clinical History

Pancreatic head cancer.

Preoperative Diagnosis

Pancreatic head mass.

Intraoperative Consultation

FSA1. RIGHT LOBE OF LIVER NODULE:
No evidence of malignancy.

FSB1. RIGHT LOBE OF LIVER NODULE NO 2:
No evidence of malignancy.

FSC1. LEFT LOBE OF LIVER NODULE:
No evidence of malignancy.

Intradepartmental Consultation: The case was also reviewed by _____, and
MD, who concur with the above interpretation.

FSD1. LIVER NODULE RIGHT LOBE, TRU-CUT:
No evidence of malignancy.

FSE1. LIVER NODULE RIGHT LOBE, TRU-CUT NO 2:
No evidence of malignancy.

FSF1. COMMON HEPATIC NODE:
Positive for tumor.

FSG1. LYMPH NODE POSTERIOR TO REPLACED RIGHT HEPATIC:
No evidence of malignancy.

FSH1. JUNCTION OF UNCINATE PROCESS, REPLACE RIGHT HEPATIC:
Lymph node tissue, positive for tumor.

FSI1. WHIPPLE, BILE DUCT MARGIN:
No evidence of malignancy.

[page 4 of 5]
FSI2. WHIPPLE, PANCREATIC MARGIN, IPMN:
No invasive carcinoma.

Intradepartmental Consultation: The case was also reviewed by _____ MD, who concurs with the above interpretation.

Comment: These frozen section diagnoses/results were communicated to and acknowledged by Dr.

I, _____ have performed the intraoperative consultations and issued the above diagnoses.

Gross Description

A. The specimen is received fresh for frozen section consultation labeled "right lobe of liver nodules" and consists of a 0.8 x 0.5 x 0.2 cm portion of firm tan tissue. The tissue is entirely frozen and submitted in FSA1.

B. The specimen is received fresh for frozen section consultation labeled "right lobe of liver nodule No 2" and consists of a 0.5 x 0.5 x 0.1 cm portion of firm tan tissue. The tissue is entirely frozen and submitted in FSB1.

C. The specimen is received fresh for frozen section consultation labeled "left lobe of liver nodules" and consists of a 1.0 x 0.5 x 0.2 cm portion of firm tan tissue. The tissue is entirely frozen and submitted in FSC1.

D. The specimen is received fresh for frozen section consultation labeled "liver nodule right lobe" and consists of a 0.1 cm in diameter elongated portion of tan tissue, which is 0.5 cm in length. The tissue is entirely frozen and submitted in FSD1.

E. The specimen is received fresh for frozen section consultation labeled "liver nodule right lobe No 2" and consists of a 0.1 cm in diameter elongated portion of tan tissue, which is 0.1 cm in length. The tissue is entirely frozen and submitted in FSE1.

F. The specimen is received fresh for frozen section consultation labeled "common hepatic node" and consists of 1 possible lymph node, which is 1.2 cm in greatest dimension. The lymph node is entirely frozen and submitted in FSF1.

G. The specimen is received fresh for frozen section consultation labeled "lymph node posterior to replaced right hepatic" and consists of a 1.5 x 1.0 x 0.1 cm possible lymph node. The tissue is entirely frozen and submitted in FSG1.

H. The specimen is received fresh for frozen section consultation labeled "junction of uncinate process and replaced right hepatic" and consists of a 1.5 x 1.0 x 0.4 cm aggregate of fragmented soft tan tissue. The tissue is entirely frozen and submitted in FSH1.

I. The specimen is received fresh for frozen section consultation labeled "Whipple, single stitch equals common bile duct margin, double stitch equals stomach, quadruple equals retroperitoneal

[page 5 of 5]
margin, triple equals pancreatic neck margin". The specimen consists of a pancreaticoduodenectomy specimen. The specimen consists of a 6.5 cm segment of stomach continuous with an 18.0 cm in length, 7.0 cm in circumference segment of small bowel with an attached 6.5 x 5.3 x 2.7 cm portion of pancreas and a 10.7 x 4.3 x 3.2 cm intact gallbladder. The ampulla of Vater is prominent and continuous with a 5.0 cm in length, 1.5 cm in diameter duct. The vascular groove is inked blue, uncinate margin is inked black, and the retroperitoneum is inked green. The pancreas is largely replaced by a 4.0 x 3.2 x 2.5 cm, ill-defined, firm, fibrous, tan mass. The mass abuts the vascular groove and is 0.1 cm from the uncinate margin and 0.4 cm from the retroperitoneum. The mass abuts and surrounds the common bile duct. No additional lesions are identified. The remaining pancreas is tan and lobulated and intermixed with thick white fibrous stroma. The gastric mucosa is erythematous and flattened. The small bowel mucosa is tan with normal folds. The wall averages 0.3 cm in thickness. There is a moderate amount of surrounding adipose tissue with surrounding adhesions. The serosa of the gallbladder is congested. The wall averages 0.3 cm in thickness. The mucosa is trabeculated and speckled yellow. The lumen contains a green, viscous bile. No stones are identified. The common bile duct margin is sectioned tangentially, frozen and entirely submitted in FS11. The pancreatic margin is sectioned tangentially, frozen and entirely submitted in FS12. Additional representative sections are submitted as follows:

- 13-14: Gastric margin, tangential
- 15: Small bowel margin, tangential
- 16: Pyloric sphincter
- 17-18: Ampulla of Vater with common bile duct and surrounding mass
- 19-113: Mass perpendicular to vascular groove, uncinate and retroperitoneal margin
- 114: Mass with adjacent normal parenchyma
- 115: Gallbladder
- 116: Normal stomach and small bowel
- 117: Normal pancreas
- 118: Five possible pancreatic lymph nodes
- 119: Two possible pancreatic lymph nodes
- 120: One possible pancreatic lymph node, sectioned
- 121: One possible pancreatic lymph node, sectioned
- 122: Four possible gastric lymph nodes
- 123: Two possible gastric lymph nodes
- 124-125: Additional gastric adipose tissue

A portion of tissue is submitted to the Tissue Procurement Laboratory.

Source: NCI Genomic Data Commons file 4c463078-51c4-4599-9477-1a73667c01ea (TCGA-3A-A9IB.4BAD0B4C-1CA9-4D06-9E93-478E35FFC613.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).